Somatic mutation profile of tumor specimen 0DM8UE from CCDI case PBCAEL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 3.0 years (1,108 days).
Specimen 0DM8UE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50ec7091-b479-41bb-9e0a-5449a6981474.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM8U7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0820620-84f2-4f52-b981-9d9ee64f5cc5

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 3, Intron 1, Nonstop Mutation 1, Nonsense Mutation 1, In Frame Ins 1, RNA 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COX6B1 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 214/2700 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as rs121909602, CM082579; ClinVar: pathogenic; called by muse, mutect2
- SMARCA4 | c.3404G>A p.R1135Q | Missense Mutation (SNP) | VAF 927/1741 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758997, COSV60787834; called by muse, mutect2, varscan2
- ADAT3 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 92/1452 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs370368743, COSV100280123; called by muse, mutect2
- EPB41 | c.1783G>A p.E595K (on ENST00000343067 / NM_001166005.2; = p.E386K on NM_004437.4) | Missense Mutation (SNP) | VAF 140/3016 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs774665169; called by muse, mutect2
- JADE2 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 787/1732 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs764992446; called by mutect2, varscan2
- MYL10 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 782/1787 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766324773, COSV99781241; called by muse, mutect2
- MYT1L | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 629/1476 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs761076416; called by muse, mutect2, varscan2
- NIM1K | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 129/1602 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.792); catalogued as rs757015659, COSV58142908; called by muse, mutect2
- NXF1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 97/1376 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as rs1256598140, COSV53677580; called by muse, mutect2
- PRUNE2 | c.8725G>A p.G2909R | Missense Mutation (SNP) | VAF 176/1808 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772474129, COSV56318019; called by muse, mutect2
- PSMD12 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 1064/2317 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370653363; called by muse, mutect2, varscan2
- QPCT | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 29/1120 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV100621491; called by muse, mutect2
- SH2D4A | c.145A>C p.K49Q | Missense Mutation (SNP) | VAF 91/2602 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV56122821; called by muse, mutect2
- VWA3B | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 103/1644 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs374632376; ClinVar: likely benign; called by muse, mutect2
- IFIT2 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 56/2294 reads (2%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KBTBD4 | c.884_889dup p.P295_R296dup | In Frame Ins (INS) | VAF 566/782 reads (72%) | called by mutect2, varscan2
- LONP1 | c.1981T>G p.Y661D | Missense Mutation (SNP) | VAF 66/1629 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- NCAN | c.2084C>A p.P695H | Missense Mutation (SNP) | VAF 41/1754 reads (2%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2
- PGAM4 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 964/2782 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLC4A7 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 106/2335 reads (5%) | called by muse, mutect2
- SYTL1 | c.1687T>C p.*563Qext*? (on ENST00000543823; = p.*551Qext*? on NM_032872.3) | Nonstop Mutation (SNP) | VAF 132/2685 reads (5%) | called by muse, mutect2
- TCN1 | c.1259T>C p.V420A | Missense Mutation (SNP) | VAF 58/1318 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- C3orf33 | c.501G>T p.V167= (on ENST00000340171 / NM_001308229.2; = p.V124= on NM_173657.2) | Silent (SNP) | VAF 348/1424 reads (24%) | called by mutect2, varscan2
- GABRG1 | c.834C>T p.Y278= | Silent (SNP) | VAF 98/2240 reads (4%) | catalogued as rs1406750682; called by muse, mutect2
- PXDN | c.2829G>T p.R943= | Silent (SNP) | VAF 39/1210 reads (3%) | called by muse, mutect2
- ATAD3B | c.645+31G>T | Intron (SNP) | VAF 531/1830 reads (29%) | called by muse, mutect2, varscan2
- CARM1 | c.-84G>T | 5'UTR (SNP) | VAF 8/58 reads (14%) | catalogued as rs868511606; called by muse, varscan2
- MUC19 | n.18789G>T | RNA (SNP) | VAF 64/1938 reads (3%) | called by muse, mutect2
- NTRK3 | c.*36C>A | 3'UTR (SNP) | VAF 94/1081 reads (9%) | catalogued as COSV100713402; called by muse, mutect2
